Gene-level copy-number profile of tumor specimen TCGA-71-6725-01A from TCGA case TCGA-71-6725, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 48.7 years (17,793 days).
Specimen TCGA-71-6725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.10bb685e-409e-4033-a9aa-eb5bad2d513a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-71-6725-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4467e54-ffa1-406a-b1a0-14cbb4bc350c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,043; copy number 2: 29,241; copy number 3: 15,569; copy number 4: 9,184; copy number 5: 2,331; copy number 6: 1,001; copy number 7: 352; copy number 8: 52; copy number 9: 18; copy number 10: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-71-6725-01A-11D-1854-01): tumor purity 0.63, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,782 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:25,087,450–31,267,610, 55 genes, copy number 5–6 (within-gene range 3–6): LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1.
- chr6:56,056,590–56,433,213, 4 genes, copy number 5 (within-gene range 2–5): COL21A1, DHFRP6, AL031779.1, RCC2P7.
- chr6:79,803,582–79,833,386, 1 gene, copy number 6 (within-gene range 1–6): LINC01621.
- chr7:70,972–146,050,366, 2,759 genes, copy number 5–7 (broad region; genes not listed).
- chr7:146,208,665–146,311,822, 2 genes, copy number 5: AC073418.1, Y_RNA.
- chr7:157,501,322–158,956,747, 20 genes, copy number 5 (within-gene range 3–5): AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1.
- chr8:93,029,751–104,256,094, 248 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:30,403,197–33,917,804, 65 genes, copy number 5 (broad region; genes not listed).
- chr10:68,260,557–69,633,596, 52 genes, copy number 8: KRT19P4, PBLD, HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA, TMEM14DP, TET1, COX20P1, RPS3AP37, AL513534.2, AL513534.3, CCAR1, Y_RNA, SNORD98, AL513534.1, STOX1, RNU6-697P, AL359844.1, DDX50, RNU6-571P, DDX21, KIFBP, MED28P1, ACTBP14, SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B.
- chr20:39,655,325–41,712,600, 29 genes, copy number 5: AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1.
- chr20:42,072,752–47,786,616, 169 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:48,624,252–48,827,999, 1 gene, copy number 5 (within-gene range 4–5): PREX1.
- chr20:48,821,688–64,313,132, 377 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,344. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
